CCDI case PBCKMY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/351dad4a-10f6-4a84-807e-7ffaeef7102a

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 11.5 years (4,214 days).

Biospecimens (3 samples)
- Sample 0DU9MG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU9N2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DU9NA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
